Somatic mutation profile of tumor specimen TCGA-ET-A40S-01A (aliquot TCGA-ET-A40S-01A-11D-A23M-08) from TCGA case TCGA-ET-A40S, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 62.2 years (22,733 days).
Specimen TCGA-ET-A40S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55370534-1eec-46f2-8d8e-2aa7a415dc07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A40S-10A (Blood Derived Normal), aliquot TCGA-ET-A40S-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9d25340-e121-448a-95d0-ff9ae78f08bf

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Frame Shift Del 3, Silent 2, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LEMD1 | c.371C>T p.T124I (on ENST00000367151; = p.P77S on NM_001001552.5) | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1021202664, COSV65672059; called by muse, mutect2, varscan2
- LILRB1 | c.1379G>A p.G460E (on ENST00000427581; = p.G424E on NM_006669.6) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as COSV61121256; called by muse, mutect2, varscan2
- MYH13 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs202246911; called by muse, mutect2, varscan2
- PLEKHA5 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1336459595, COSV54711082; called by muse, mutect2, varscan2
- SMARCD3 | c.1273C>T p.R425C (on ENST00000262188 / NM_001003801.2; = p.R412C on NM_003078.4) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1028309748, COSV50398942; called by muse, mutect2, varscan2
- SNX9 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV67585819; called by muse, varscan2
- TRAK1 | c.225T>G p.I75M | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.214); catalogued as COSV59647106; called by muse, mutect2, varscan2
- A2ML1 | c.806_807del p.E269Gfs*8 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | called by pindel, varscan2
- ABTB2 | c.2140_2149del p.T714Yfs*20 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- AC144573.1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- ARHGAP29 | c.1703del p.P568Hfs*15 | Frame Shift Del (DEL) | VAF 18/127 reads (14%) | called by mutect2, pindel, varscan2
- DDIT4 | c.205+4_205+10del p.X69_splice | Splice Site (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- HSPA4 | c.577_582del p.E193_K194del | In Frame Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- RASEF | c.1911dup p.M638Yfs*3 | Frame Shift Ins (INS) | VAF 8/55 reads (15%) | called by mutect2, pindel
- MIER2 | c.156G>A p.Q52= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV53397936; called by muse, mutect2, varscan2
- PPL | c.4116C>T p.A1372= | Silent (SNP) | VAF 33/259 reads (13%) | catalogued as rs1179098036, COSV52172363; called by muse, mutect2, varscan2
